Somatic mutation profile of tumor specimen C3L-08660-03 (aliquot CPT0482110006) from CPTAC case C3L-08660, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 78.4 years (28,643 days).
Specimen C3L-08660-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9cfcef5-8f9f-426a-af95-fed41b43673d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08660-31 (Blood Derived Normal), aliquot CPT0482180003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdefc9a1-1c51-44ce-98c4-ab93974627e0

The open-access MAF lists 117 somatic variants for this specimen: 80 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 34, Nonsense Mutation 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 32/245 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs752416597; called by muse, mutect2
- ADNP | c.3226C>G p.Q1076E | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.069); catalogued as rs1283913077; called by muse, mutect2
- ATXN2L | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 46/438 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs150384100; called by muse, mutect2
- CCNA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 65/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765233671, COSV55220035; called by muse, mutect2, varscan2
- CDH5 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58519902; called by muse, mutect2
- CNGB3 | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60694507; called by muse, mutect2, varscan2
- CTSG | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1475145065, COSV53535207, COSV99361723; called by muse, mutect2, varscan2
- DCT | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 23/445 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs542143928; called by muse, mutect2
- DLGAP2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 38/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428611888; called by muse, mutect2
- FAM155A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV101030740, COSV65590911; called by muse, mutect2, varscan2
- FASTKD3 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 45/420 reads (11%) | catalogued as COSV99241987; called by muse, mutect2, varscan2
- FAT3 | c.1700G>C p.R567P | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.759); catalogued as COSV53107644; called by muse, mutect2
- FLG | c.5930C>A p.S1977* | Nonsense Mutation (SNP) | VAF 33/598 reads (6%) | catalogued as rs140980397; called by muse, mutect2
- GABRA2 | c.719T>G p.M240R | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62918394; called by muse, mutect2
- GFPT2 | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53807724; called by muse, mutect2
- GRM7 | c.1904G>A p.G635D | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63141451; called by muse, mutect2
- HEPHL1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779368553, COSV59893961; called by muse, mutect2
- HEXA | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99173808; called by muse, mutect2
- KCNK15 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 44/411 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.307); catalogued as rs1294846237; called by muse, mutect2, varscan2
- KIFC2 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as rs758933084; called by muse, mutect2, varscan2
- MASP1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs536677365; called by muse, mutect2, varscan2
- MED12 | c.2121G>C p.E707D | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV100379896; called by muse, mutect2
- MGAM | c.3524G>C p.G1175A | Missense Mutation (SNP) | VAF 39/448 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761637327; called by muse, mutect2
- MRM1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 56/653 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1335959651; called by muse, mutect2
- NRXN1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as rs201966126, COSV101277659, COSV68003819; called by muse, mutect2, varscan2
- NRXN3 | c.1457T>C p.M486T | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1026163579; called by muse, mutect2
- OR1R1P | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 63/391 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1258481435; called by muse, mutect2, varscan2
- OR4K1 | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 30/784 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1030569841; called by muse, mutect2
- PCDH10 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 44/431 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1320022157; called by muse, mutect2, varscan2
- PCDHA8 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs146582216, COSV65323904; called by muse, mutect2, varscan2
- POU5F2 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV67938815; called by muse, mutect2, varscan2
- PTPRM | c.3379G>A p.V1127I | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as rs761396528, COSV59849178; called by muse, mutect2, varscan2
- RALGAPA2 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52509993; called by muse, mutect2
- SOAT2 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs757794445, COSV100037590; called by muse, mutect2, varscan2
- TACR1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs371933483; called by muse, mutect2
- TERF2IP | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs1345270447; called by muse, varscan2
- THSD7A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769058292, COSV70262329; called by muse, mutect2
- TMEM132C | c.3002G>C p.G1001A | Missense Mutation (SNP) | VAF 14/471 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV100175058; called by muse, mutect2
- TMEM185B | c.233G>C p.C78S | Missense Mutation (SNP) | VAF 62/479 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as rs772321018; called by muse, mutect2, varscan2
- VWF | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 49/504 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs770786924, COSV54612216; called by muse, mutect2
- ZNF616 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs781207679; called by muse, mutect2
- ZNF629 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 49/554 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1459597716, COSV52699841; called by muse, mutect2
- AGBL2 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AP002748.5 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- BOLA3 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 31/286 reads (11%) | called by muse, mutect2, varscan2
- CALHM6 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- CCDC154 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2
- DCDC1 | c.4855C>T p.Q1619* (on ENST00000597505 / NM_001367979.1; = p.Q726* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 34/364 reads (9%) | called by muse, mutect2
- DLGAP2 | c.2655G>T p.W885C | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM184B | c.3176C>G p.S1059C | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBRSL1 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 37/556 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- FOXM1 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2
- HIVEP3 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 33/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITSN2 | c.3701T>G p.V1234G | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2K7 | c.1103G>C p.R368T | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MELK | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MXRA5 | c.5641C>T p.P1881S | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NBEAL2 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPCML | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PGBD1 | c.362A>C p.N121T | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2
- PMAIP1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by mutect2, varscan2
- PPP1R3A | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.119); called by muse, mutect2
- PRRG3 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 37/494 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF182 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SETBP1 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SLC15A4 | c.1446G>T p.K482N | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SLC30A8 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRCIN1 | c.3350A>G p.D1117G (on ENST00000621492; = p.D1083G on NM_025248.3) | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- SSNA1 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- SUCLG1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2
- SZT2 | c.3485C>G p.T1162R (on ENST00000634258 / NM_001365999.1; = p.T1105R on NM_015284.4) | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2
- TARS2 | c.1721A>T p.Q574L | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2
- TERF2 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.535); called by muse, mutect2
- TGFB2 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, varscan2
- THAP9 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- TMF1 | c.2952C>A p.S984R | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP29 | c.1896G>T p.L632F | Missense Mutation (SNP) | VAF 21/363 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2
- ZNF254 | c.628T>A p.Y210N | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ZNF444 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 54/523 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKS3 | c.87C>T p.S29= | Silent (SNP) | VAF 44/509 reads (9%) | catalogued as rs774565232; called by muse, mutect2
- ARHGAP33 | c.84G>T p.V28= | Silent (SNP) | VAF 43/527 reads (8%) | called by muse, mutect2
- ATAD2 | c.2094G>A p.G698= | Silent (SNP) | VAF 19/572 reads (3%) | called by muse, mutect2
- B3GAT1 | c.471C>T p.D157= | Silent (SNP) | VAF 50/656 reads (8%) | catalogued as rs761344039, COSV56998057, COSV56998905; called by muse, mutect2
- CCK | c.27G>A p.V9= | Silent (SNP) | VAF 49/333 reads (15%) | called by muse, mutect2, varscan2
- CD300LB | c.258G>A p.T86= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as rs763129538, COSV58725218; called by muse, mutect2
- CDCA2 | c.1770C>A p.L590= | Silent (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2, varscan2
- CLEC16A | c.1047T>C p.T349= | Silent (SNP) | VAF 28/242 reads (12%) | catalogued as rs1430317731; called by muse, mutect2, varscan2
- COL1A2 | c.3219A>T p.T1073= | Silent (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- CRHBP | c.78A>G p.L26= | Silent (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2
- CSMD1 | c.4038G>A p.L1346= (on ENST00000520002; = p.L1345= on NM_033225.6) | Silent (SNP) | VAF 34/413 reads (8%) | catalogued as rs773168599, COSV100145828; called by muse, mutect2
- DIRAS2 | c.495G>T p.L165= | Silent (SNP) | VAF 31/284 reads (11%) | catalogued as COSV101005854; called by muse, mutect2, varscan2
- FGF4 | c.111C>A p.G37= | Silent (SNP) | VAF 48/517 reads (9%) | called by muse, mutect2
- FZD8 | c.27G>C p.V9= | Silent (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- GRIA2 | c.66C>G p.V22= | Silent (SNP) | VAF 23/311 reads (7%) | called by muse, mutect2
- HPX | c.180C>T p.T60= | Silent (SNP) | VAF 23/322 reads (7%) | catalogued as rs149506788; called by muse, mutect2
- LARGE2 | c.2013G>C p.L671= | Silent (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- NPNT | c.927G>A p.R309= | Silent (SNP) | VAF 23/498 reads (5%) | catalogued as rs1467938999, COSV99974665; called by muse, mutect2
- OSBPL9 | c.567C>T p.H189= | Silent (SNP) | VAF 21/288 reads (7%) | catalogued as rs370193883; called by muse, mutect2
- PLEC | c.11685C>T p.H3895= (on ENST00000322810 / NM_201380.4; = p.H3785= on NM_000445.5) | Silent (SNP) | VAF 65/518 reads (13%) | catalogued as rs530897932, COSV100513615; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3F | c.867C>T p.P289= | Silent (SNP) | VAF 48/617 reads (8%) | catalogued as rs376213043, COSV50019314; called by muse, mutect2
- PPP6R3 | c.861A>T p.I287= | Silent (SNP) | VAF 27/261 reads (10%) | called by muse, mutect2, varscan2
- PRPF6 | c.2796G>T p.L932= | Silent (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- RNF144A | c.681C>T p.Y227= | Silent (SNP) | VAF 23/402 reads (6%) | catalogued as rs573785745; called by muse, mutect2
- RNF25 | c.723C>G p.L241= | Silent (SNP) | VAF 39/427 reads (9%) | called by muse, mutect2
- SDK1 | c.5079G>A p.E1693= | Silent (SNP) | VAF 34/324 reads (10%) | called by muse, mutect2, varscan2
- TAS1R2 | c.2100G>A p.T700= | Silent (SNP) | VAF 30/474 reads (6%) | catalogued as rs374616366; called by muse, mutect2
- TDRD12 | c.276T>C p.C92= | Silent (SNP) | VAF 48/347 reads (14%) | called by muse, mutect2, varscan2
- TENM1 | c.5544G>A p.S1848= | Silent (SNP) | VAF 62/441 reads (14%) | catalogued as rs1299717181; called by muse, mutect2, varscan2
- TLX2 | c.255G>A p.A85= | Silent (SNP) | VAF 55/601 reads (9%) | called by muse, mutect2
- TTN | c.69516T>G p.T23172= (on ENST00000591111; = p.T15748= on NM_003319.4) | Silent (SNP) | VAF 54/449 reads (12%) | catalogued as rs1221079426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13C | c.7227C>A p.G2409= (on ENST00000644861 / NM_020821.3; = p.G2366= on NM_017684.5) | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- XKR4 | c.1560C>T p.F520= | Silent (SNP) | VAF 28/268 reads (10%) | catalogued as rs773989931, COSV59312417; called by muse, varscan2
- ZNF77 | c.438G>A p.K146= | Silent (SNP) | VAF 48/389 reads (12%) | catalogued as COSV100094711; called by muse, mutect2, varscan2
- DNAJC12 | c.158-4435A>T | Intron (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- RIMBP2 | c.*1647C>A | 3'UTR (SNP) | VAF 18/402 reads (4%) | called by muse, mutect2
- ZSCAN32 | c.839-703G>A | Intron (SNP) | VAF 42/528 reads (8%) | called by muse, mutect2
